Somatic mutation profile of tumor specimen TCGA-CQ-6229-01A (aliquot TCGA-CQ-6229-01A-11D-1912-08) from TCGA case TCGA-CQ-6229, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tongue, NOS; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 61.7 years (22,541 days).
Specimen TCGA-CQ-6229-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7e33b90e-b00b-480c-9f37-4941159eb597.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CQ-6229-10A (Blood Derived Normal), aliquot TCGA-CQ-6229-10A-01D-1912-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2ac2861f-199a-4e42-80d3-38463f64634c

The open-access MAF lists 31 somatic variants for this specimen: 21 protein-altering or splice-affecting, 8 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 19, Silent 8, Intron 2, Nonsense Mutation 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.637C>T p.R213* | Nonsense Mutation (SNP) | VAF 18/28 reads (64%) | hotspot (GDC flag); catalogued as rs397516436, CM951226, COSV52665560, COSV52740638, COSV52746781, COSV52782151; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ALOXE3 | c.2053G>A p.D685N | Missense Mutation (SNP) | VAF 7/152 reads (5%) | SIFT tolerated (0.26); PolyPhen benign (0.014); catalogued as COSV100560001; called by muse, mutect2
- APCDD1L | c.1426C>G p.P476A | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT tolerated (0.77); PolyPhen benign (0.003); catalogued as COSV100954107; called by muse, mutect2, varscan2
- CCL3 | c.89C>T p.P30L | Missense Mutation (SNP) | VAF 14/190 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.751); catalogued as rs368462880; called by muse, mutect2
- CLC | c.245C>T p.P82L | Missense Mutation (SNP) | VAF 11/109 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.954); catalogued as COSV99695686; called by muse, mutect2
- CRACR2B | c.229C>T p.R77W | Missense Mutation (SNP) | VAF 8/110 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.406); catalogued as rs1300195939, COSV58990863; called by muse, mutect2
- HCFC1R1 | c.248C>T p.P83L | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.039); catalogued as COSV99560829; called by mutect2, varscan2
- KIF1A | c.4828C>A p.P1610T (on ENST00000320389 / NM_001379639.1; = p.P1602T on NM_004321.8 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/108 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100242489; called by muse, mutect2
- KRT28 | c.1028C>T p.T343M | Missense Mutation (SNP) | VAF 41/208 reads (20%) | SIFT tolerated (0.2); PolyPhen benign (0.029); catalogued as rs776024934, COSV100137759; called by muse, mutect2, varscan2
- MINDY4 | c.734G>A p.S245N | Missense Mutation (SNP) | VAF 16/158 reads (10%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs1328626200, COSV99519370; called by muse, mutect2, varscan2
- MORC2 | c.2665T>G p.S889A (on ENST00000397641 / NM_001303256.3; = p.S827A on NM_014941.3) | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.952); catalogued as COSV99310517; called by muse, mutect2, varscan2
- NR6A1 | c.1216A>C p.T406P (on ENST00000487099 / NM_033334.4; = p.T401P on NM_001489.5) | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.53); catalogued as rs767988049, COSV100748720; called by muse, mutect2, varscan2
- NUAK2 | c.188C>T p.T63I | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs904918812, COSV65682453; called by muse, mutect2, varscan2
- PLXNA1 | c.348G>T p.K116N | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99304219; called by muse, mutect2, varscan2
- SEPTIN4 | c.86C>T p.T29M | Missense Mutation (SNP) | VAF 16/158 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.178); catalogued as rs755554839, COSV100422194, COSV57900524; called by muse, mutect2
- STC2 | c.71G>T p.G24V | Missense Mutation (SNP) | VAF 19/106 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV54180398, COSV99438750; called by muse, mutect2, varscan2
- UCP3 | c.331G>A p.A111T | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs376385271, COSV100012909; called by muse, mutect2, varscan2
- UGT2B4 | c.932C>T p.S311L | Missense Mutation (SNP) | VAF 46/228 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779529648, COSV59315552; called by muse, mutect2, varscan2
- UPF3A | c.328C>T p.L110F | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); catalogued as rs940862875, COSV100677739; called by muse, mutect2
- ZSCAN32 | c.1065G>T p.Q355H (on ENST00000396846; = p.Q376H on NM_017810.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.041); catalogued as COSV100514604; called by muse, mutect2, varscan2
- MAPRE1 | c.356_357del p.Y119* | Frame Shift Del (DEL) | VAF 14/121 reads (12%) | called by mutect2, pindel, varscan2
- CPT1A | c.1368G>A p.S456= | Silent (SNP) | VAF 17/74 reads (23%) | catalogued as rs563338783, COSV99681646; called by muse, mutect2, varscan2
- OBSCN | c.2925C>T p.V975= | Silent (SNP) | VAF 5/46 reads (11%) | catalogued as COSV99484812; called by muse, mutect2
- RUNX1T1 | c.1320C>T p.Y440= (on ENST00000265814 / NM_001198628.1; = p.Y413= on NM_004349.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 29/185 reads (16%) | catalogued as rs537704114, COSV56159338; called by muse, mutect2, varscan2
- SEMA3D | c.1410A>C p.G470= | Silent (SNP) | VAF 20/149 reads (13%) | catalogued as COSV99407501; called by muse, varscan2
- SKIV2L | c.483A>G p.E161= | Silent (SNP) | VAF 42/184 reads (23%) | catalogued as COSV100952878; called by muse, mutect2, varscan2
- SKIV2L | c.1663C>T p.L555= | Silent (SNP) | VAF 80/268 reads (30%) | catalogued as COSV100952879; called by muse, mutect2, varscan2
- TNR | c.2431A>C p.R811= | Silent (SNP) | VAF 18/68 reads (26%) | catalogued as COSV99691811; called by muse, mutect2, varscan2
- ZSCAN2 | c.1752G>A p.K584= | Silent (SNP) | VAF 11/84 reads (13%) | catalogued as COSV100306978; called by muse, mutect2, varscan2
- MELTF | c.712+1614C>T | Intron (SNP) | VAF 6/64 reads (9%) | catalogued as rs149352003; called by muse, mutect2
- SKP2 | c.1062-1585C>G | Intron (SNP) | VAF 17/174 reads (10%) | called by muse, mutect2, varscan2
